Surgical pathology report (de-identified scan), TCGA case TCGA-WQ-AB4B, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site University of Kansas, specimen TCGA-WQ-AB4B-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

NAME:

MR #:

BILLING #:

LOCATION:

AGE:

SEX: M

DOB:

PHYSICIAN:

COPY TO:

SURG PATH #:

SPECIMEN CLASS:

ALT ID #:

DATE OF PROCEDURE:

DATE RECEIVED:

TIME RECEIVED:

DATE OF REPORT:

DATE OF PRINTING:

Material Received:

A. liver mass

History:

-year-old male with a clinical history of cirrhosis, liver mass.

ICD-O 3
Carcinoma, Hepato. (C22.0) NOS S170/3
Site: Liver C22.0
J2 6/30/14

Final Diagnosis:

A. Liver, "liver mass", resection:

Hepatocellular carcinoma (3.0 cm), moderately differentiated, in a background of cirrhosis, clinically non-alcoholic steatohepatitis.

Comment:

Liver (Hepatectomy)-HCC

Specimen Type: Wedge resection

Tumor Size: 3.0 cm

Tumor Focality: Solitary

Histologic Type: Hepatocellular carcinoma (patchy intratumoral fibrosis is present)

Histologic Grade:

GII: Moderately differentiated

Tumor Extension:

Tumor confined to liver

History of previous treatment (TACE or RFA): No

Treatment Effect: N/A

Margins:

Parenchymal Margin:

Uninvolved by invasive carcinoma

Distance of invasive carcinoma from closest margin: 0.8 cm

Vascular Invasion:

Macroscopic Venous (Large Vessel) Invasion (V): Absent

Microscopic (Small Vessel) Invasion (L): Present

Lymph Nodes: Not applicable

Additional Pathologic Findings: Cirrhosis, clinically non-alcoholic steatohepatitis

Pathologic Staging: pT2Nx

TNM Descriptors

m (multiple primary tumors)

r (recurrent)

y (post-treatment)

MR #:

Page 1 of 2

Date of Printing:

Order Number

SURGICAL PATHOLOGY REPORT

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

NAME:
MR #:

SURG PATH #:
ALT ID #:

Primary Tumor (pT)

pT2: Solitary tumor with vascular invasion or multiple tumors none more than 5 cm

Regional Lymph Nodes (pN)

pNX: Cannot be assessed

Distant Metastasis (pM)

Not applicable

The pathologic stage assigned here should be regarded as provisional, as it reflects only current pathologic data and does not incorporate full knowledge of the patient's clinical status and/or prior pathology.

Pursuant to the _____ this case has been concurrently reviewed by the following pathologist: _____ who agrees with the above diagnosis.

Attestation:

By this signature, I attest that I have personally formulated the final interpretation expressed in this report and that the above diagnosis is based upon my examination of the slides and/or other material indicated in this report.

Electronically Signed Out By

Interpreted by:

Gross Description:

A. Received fresh labeled with the patient's name and "liver mass" is a liver wedge resection which weighs 346 grams and measures 6.0 x 4.2 x 3.4 cm. The resection margin is red-brown and ragged, and demonstrates multiple staples; the resection margin is inked black. The capsule is red-brown, smooth to focally nodular. The specimen is perviously incised to reveal a 3.0 x 2.4 x 2.4 cm mass which bulges the capsule and is located 1.4 cm from the nearest resection margin. The cut surfaces of the mass are tan, smooth and solid. The remainder of the liver parenchyma is tan-pink and uniformly nodular. A representative portion of the mass and the liver parenchyma is submitted for tumor bank.

- A1 Mass in relation to nearest resection margin.
- A2 Mass in relation to resection margin.
- A3 Additional section of mass.
- A4-A5 One complete cross section of the mass, bisected.
- A6 Liver parenchyma, not grossly involved with the mass

MR #:

Page 2 of 2

Date of Printing:

SURGICAL PATHOLOGY REPORT

Source: NCI Genomic Data Commons file 966a1e16-9398-410e-9c3d-e1b7937808b0 (TCGA-WQ-AB4B.A0DBAC80-0D07-41BD-9AD2-E73D2DE2FBC7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).